Gene-level copy-number profile of tumor specimen ALCH-B1JI-TTP1-A from ALCHEMIST case ALCH-B1JI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 46.5 years (16,971 days).
Specimen ALCH-B1JI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1bf867b3-f0d7-4a90-969a-ba50ce300878.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1JI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/4aaee627-bcaf-4d15-a5c7-8c39a0901c17

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 124; copy number 1: 3,300; copy number 2: 52,288; copy number 3: 2,612; copy number 4: 48; copy number 5: 12; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 123 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–2): AL139423.1.
- chr1:12,644,547–12,667,086, 1 gene: AADACL4.
- chr2:44,921,077–44,946,071, 11 genes: LINC01833, AC012354.9, AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3.
- chr2:127,048,027–127,107,288, 1 gene: BIN1.
- chr2:241,808,312–241,817,413, 2 genes: AC131097.2, NEU4.
- chr5:139,647,299–139,683,882, 2 genes (within-gene range 0–2): CXXC5, CXXC5-AS1.
- chr5:146,706,381–146,707,600, 1 gene (within-gene range 0–2): KRT8P48.
- chr6:35,765,908–35,779,552, 2 genes: AL157823.1, CLPSL2.
- chr7:5,592,816–5,606,655, 1 gene: FSCN1.
- chr7:43,961,590–43,990,207, 2 genes (within-gene range 0–2): AC004951.3, AC004951.2.
- chr7:76,959,835–77,043,775, 1 gene (within-gene range 0–2): DTX2P1-UPK3BP1-PMS2P11.
- chr7:76,978,617–77,032,361, 5 genes (within-gene range 0–2): DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17.
- chr8:9,658,295–9,658,438, 1 gene (within-gene range 0–1): AC103834.1.
- chr8:20,246,165–20,303,963, 1 gene (within-gene range 0–1): LZTS1.
- chr8:37,784,191–37,844,896, 1 gene (within-gene range 0–2): ADGRA2.
- chr9:41,340,823–41,355,538, 1 gene: CDRT15P6.
- chr11:45,905,941–45,918,812, 3 genes (within-gene range 0–2): AC068385.1, C11orf94, PEX16.
- chr11:46,277,662–46,386,608, 5 genes: CREB3L1, DGKZ, MIR4688, MDK, CHRM4.
- chr11:64,340,204–64,372,215, 4 genes (within-gene range 0–2): CCDC88B, MIR7155, RPS6KA4, MIR1237.
- chr14:100,323,339–100,354,061, 2 genes (within-gene range 0–3): SLC25A47, AL157871.4.
- chr14:100,339,832–100,340,554, 1 gene (within-gene range 0–3): AL157871.2.
- chr14:105,419,820–105,470,729, 2 genes (within-gene range 0–2): MTA1, AL928654.2.
- chr15:25,169,337–25,250,940, 45 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:45,129,933–45,167,526, 2 genes (within-gene range 0–2): DUOX1, AC051619.5.
- chr15:64,739,891–64,775,589, 2 genes: RBPMS2, MIR1272.
- chr15:85,750,336–85,794,925, 5 genes: AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr16:70,852,698–70,852,814, 1 gene (within-gene range 0–2): RNU6ATAC25P.
- chr16:89,906,157–89,938,761, 5 genes (within-gene range 0–1): AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3.
- chr17:2,017,716–2,023,664, 2 genes (within-gene range 0–1): AC099684.1, AC099684.3.
- chr17:4,538,897–4,560,818, 2 genes (within-gene range 0–1): MYBBP1A, GGT6.
- chr18:37,273,706–37,306,333, 2 genes (within-gene range 0–2): AC090386.1, AC090386.2.
- chr22:29,705,256–29,767,011, 5 genes (within-gene range 0–2): AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:68,232,003–68,300,035, 2 genes, copy number 6: CBWD3, AL353608.4.
- chr16:2,339,150–2,426,699, 1 gene, copy number 5 (within-gene range 2–5): ABCA17P.
- chr16:30,182,827–30,254,510, 11 genes, copy number 5: CORO1A, AC012645.3, BOLA2B, SLX1A, SLX1A-SULT1A3, SULT1A3, AC106782.1, AC106782.6, AC106782.3, AC106782.2, NPIPB13.

Autosomal genes at a single copy (total copy number 1): 2,308. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
